Gene-level copy-number profile of tumor specimen RC-B6SF-TBP1-A from RC case RC-B6SF, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 61.6 years (22,500 days).
Specimen RC-B6SF-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e06350ad-501e-49a3-b974-11e0c8d2227c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6SF-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/5815078e-9a10-4484-89ab-72cd88e2a2f4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 182; copy number 1: 16,565; copy number 2: 37,320; copy number 3: 4,777; copy number 4: 31; copy number 5: 26.

Homozygous deletions (total copy number 0; autosomes only): 182 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:111,119,378–111,279,880, 6 genes (within-gene range 0–1): BCL2L11, AC108463.2, AC108463.1, AC108463.3, AC068491.1, AC068491.2.
- chr7:38,239,580–38,378,804, 24 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:142,641,746–142,802,748, 32 genes (within-gene range 0–3): TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr12:12,715,058–12,829,975, 6 genes (within-gene range 0–1): CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1.
- chr13:48,389,567–48,444,704, 2 genes (within-gene range 0–1): LPAR6, Metazoa_SRP.
- chr13:49,956,670–50,125,720, 12 genes (within-gene range 0–1): DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,082,484, 1 gene (within-gene range 0–1): AL137060.6.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr14:22,066,016–22,552,156, 94 genes (within-gene range 0–2) (broad region; genes not listed).
- chr19:10,960,932–11,079,426, 4 genes: SMARCA4, AC011442.1, RN7SL192P, AC006127.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:35,352,482–35,645,180, 26 genes, copy number 5: C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1.

Autosomal genes at a single copy (total copy number 1): 14,221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
